MMRF case MMRF_2207 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7aa5dcf1-d948-4e0f-9740-c2d2836840d4

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.2 years (20,891 days); ISS stage: I; Days to last known disease status: 872 days (2.4 years); Days to last follow up: 872 days (2.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 122 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 172 days; Days to treatment end: 172 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 173 days; Days to treatment end: 173 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days; Days to treatment end: 802 days (2.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 323 days.
   Treatment given: Therapeutic agents: Ixazomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 802 days (2.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -17 (ECOG 0): M Protein 3.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.361 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.64 mg/dL; Immunoglobulin G 46.3 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.47 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 3.03 mmol/L; Albumin 37 g/L; Total Protein 9.3 g/dL; Glucose 5.72 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 82 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.691 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.892 mg/dL; Immunoglobulin G 6.77 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.5 g/L; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 4.84 mmol/L.
- Day 152 (ECOG 1): M Protein 0.04 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.583 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.84 mg/dL; Immunoglobulin G 8.54 g/L; Immunoglobulin A 0.74 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.93 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 6.38 mmol/L.
- Day 238 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.12 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.98 mg/dL; Immunoglobulin G 13.8 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 1.33 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 101 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 7.1 g/dL; Glucose 5.78 mmol/L.
- Day 288 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.76 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.54 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.77 g/L; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 105 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 5.34 mmol/L.
- Day 379: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 7.35 g/L; Immunoglobulin A 0.69 g/L; Immunoglobulin M 0.88 g/L; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 4.57 mmol/L.
- Day 558 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.74 mg/dL; Immunoglobulin G 7.21 g/L; Immunoglobulin A 1.87 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 3.03 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.5 mmol/L.
- Day 712 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.59 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 3.41 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 3.02 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 150 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 5.9 g/dL; Glucose 5.61 mmol/L.
- Day 802 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.69 mg/dL; Immunoglobulin G 7.57 g/L; Immunoglobulin A 0.8 g/L; Immunoglobulin M 0.28 g/L; Beta 2 Microglobulin 2.09 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.03 mmol/L; Albumin 38 g/L; Total Protein 6.2 g/dL; Glucose 5.34 mmol/L.
- Day 872 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Immunoglobulin G 8.64 g/L; Immunoglobulin A 0.98 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.45 mmol/L.

Other clinical attributes
- Day -17: Weight: 99 kg; Height: 185 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2207_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -17 days.
- Sample MMRF_2207_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -17 days.
